Gene-level copy-number profile of tumor specimen TCGA-04-1356-01A from TCGA case TCGA-04-1356, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 62.6 years (22,855 days).
Specimen TCGA-04-1356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.72a0595a-c9a2-4424-bbfc-1b63c7c21489.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1356-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e47f1ac-c5f1-4192-ad72-51ff6543d74e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 82; copy number 2: 21,629; copy number 3: 13,468; copy number 4: 18,434; copy number 5: 377; copy number 6: 4,940; copy number 7: 31; copy number 8: 438; copy number 9: 324; copy number 13: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1356-01A-01D-0452-01): tumor purity 0.71, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:14,027,419–18,760,320, 76 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,121 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,175,073–46,900,437, 27 genes, copy number 6: TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8.
- chr1:91,642,516–91,644,082, 1 gene, copy number 5: HSP90B3P.
- chr1:153,373,711–156,395,609, 187 genes, copy number 6 (broad region; genes not listed).
- chr1:156,420,341–156,420,429, 1 gene, copy number 6: MIR9-1.
- chr1:178,479,247–179,229,684, 23 genes, copy number 5: CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1, FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3.
- chr1:201,896,456–202,189,455, 17 genes, copy number 7 (within-gene range 4–7): LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP.
- chr1:209,147,220–248,919,946, 868 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:100,642,444–103,019,900, 45 genes, copy number 6 (within-gene range 4–6): AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796.
- chr2:163,743,913–225,042,468, 1,008 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:149,474,697–189,325,304, 656 genes, copy number 6 (broad region; genes not listed).
- chr3:189,645,327–189,645,466, 1 gene, copy number 6: AC078809.1.
- chr3:190,120,964–190,167,651, 3 genes, copy number 8: P3H2-AS1, RNU6-1109P, NMNAT1P3.
- chr3:197,578,213–198,222,513, 27 genes, copy number 6: AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:1,166,932–2,242,276, 30 genes, copy number 6 (within-gene range 4–6): SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2.
- chr4:112,755,816–112,798,691, 3 genes, copy number 6: Y_RNA, RPL7AP30, AC017007.4.
- chr4:112,826,307–112,882,330, 3 genes, copy number 6: AC017007.2, AC017007.5, AC017007.1.
- chr4:128,292,751–128,875,224, 6 genes, copy number 6 (within-gene range 4–6): LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1.
- chr5:58,198–4,874,759, 101 genes, copy number 5–6 (broad region; genes not listed).
- chr6:135,239,160–137,544,372, 44 genes, copy number 6: MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3, BTF3L4P3.
- chr6:147,660,703–149,076,990, 13 genes, copy number 6 (within-gene range 2–6): AL033504.1, AL365271.1, AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST.
- chr8:69,466,624–69,660,915, 1 gene, copy number 6 (within-gene range 4–6): SULF1.
- chr8:81,439,436–109,899,762, 463 genes, copy number 6 (broad region; genes not listed).
- chr8:124,539,101–139,127,953, 170 genes, copy number 6 (broad region; genes not listed).
- chr8:141,507,333–141,662,209, 3 genes, copy number 6: AC138647.2, AC138647.1, AC025839.1.
- chr9:130,892,707–130,945,520, 3 genes, copy number 6: QRFP, FIBCD1, AL161733.1.
- chr10:25,647,570–25,732,935, 3 genes, copy number 6 (within-gene range 4–6): GPN3P1, LINC00836, HIRAP1.
- chr10:100,463,009–100,559,998, 5 genes, copy number 6 (within-gene range 4–6): WNT8B, SEC31B, AL133352.1, NDUFB8, HIF1AN.
- chr11:26,559,032–27,127,809, 4 genes, copy number 5 (within-gene range 4–5): MUC15, SLC5A12, FIBIN, BBOX1.
- chr11:60,916,339–61,369,509, 19 genes, copy number 5 (within-gene range 4–5): AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE, DDB1, TKFC, CYB561A3, AP003108.3, TMEM138.
- chr12:66,767–32,100,735, 809 genes, copy number 6–9 (broad region; genes not listed).
- chr14:43,274,824–48,046,216, 49 genes, copy number 6: TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3, MIR548Y, LINC00648, AL121576.1, AL359212.1.
- chr17:2,557,753–5,731,085, 149 genes, copy number 5 (broad region; genes not listed).
- chr17:49,966,075–83,095,122, 993 genes, copy number 6–13 (broad region; genes not listed).
- chr20:87,250–2,641,784, 77 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:4,023,917–4,075,165, 3 genes, copy number 8 (within-gene range 4–8): FTLP3, RPL21P2, AL356414.1.
- chr20:8,077,251–20,854,642, 183 genes, copy number 6 (broad region; genes not listed).
- chr20:31,819,308–32,743,567, 35 genes, copy number 5: MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7.
- chr20:60,812,004–60,814,211, 1 gene, copy number 7: AL139348.1.
- chr20:63,116,218–63,969,930, 60 genes, copy number 6: AL096828.6, AL096828.2, AL096828.5, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B.
- chr22:23,059,415–23,638,941, 27 genes, copy number 5–8 (within-gene range 4–8): RSPH14, GNAZ, Metazoa_SRP, U7, RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1.

Autosomal genes at a single copy (total copy number 1): 82. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
